Gene-level copy-number profile of tumor specimen TCGA-G2-A3VY-01A from TCGA case TCGA-G2-A3VY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,112 days).
Specimen TCGA-G2-A3VY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8f1e78c7-d264-4497-bba0-0999e6dcd2c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A3VY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4df73d8-cd73-476f-9633-a985f3ed1c8d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,427; copy number 2: 15,989; copy number 3: 18,821; copy number 4: 11,989; copy number 5: 6,876; copy number 6: 1,711; copy number 7: 1,910; copy number 8: 565; copy number 9: 124; copy number 10: 162; copy number 11: 144; copy number 12: 6; copy number 13: 26; copy number 14: 43; copy number 16: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A3VY-01A-11D-A22Y-01): tumor purity 0.9, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,995 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,983,435–236,502,915, 90 genes, copy number 9–11 (broad region; genes not listed).
- chr2:17,385,091–22,536,322, 72 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:49,202,126–71,984,434, 374 genes, copy number 7 (broad region; genes not listed).
- chr2:79,185,231–80,648,861, 1 gene, copy number 7 (within-gene range 5–7): CTNNA2.
- chr2:79,866,495–80,870,190, 6 genes, copy number 7: MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1.
- chr2:152,850,653–158,935,985, 73 genes, copy number 7–10 (broad region; genes not listed).
- chr2:159,003,975–159,056,859, 3 genes, copy number 10: BTF3L4P2, RNU6-580P, GSTM3P2.
- chr2:159,235,798–167,259,753, 92 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:167,814,757–170,120,098, 35 genes, copy number 8 (within-gene range 3–8): B3GALT1-AS1, B3GALT1, STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2, BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P.
- chr3:178,960,121–180,037,053, 27 genes, copy number 8 (within-gene range 4–8): ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2.
- chr5:21,750,673–22,853,344, 1 gene, copy number 8 (within-gene range 6–8): CDH12.
- chr5:22,139,247–37,085,852, 199 genes, copy number 7–8 (broad region; genes not listed).
- chr6:167,607–1,528,911, 30 genes, copy number 7: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2.
- chr6:11,414,636–18,368,644, 105 genes, copy number 7–13 (broad region; genes not listed).
- chr6:19,143,695–24,666,930, 62 genes, copy number 7–16 (broad region; genes not listed).
- chr7:42,661,716–42,844,438, 3 genes, copy number 7: LINC01448, TCP1P1, AC010132.1.
- chr7:56,228,634–57,610,104, 78 genes, copy number 8 (broad region; genes not listed).
- chr8:34,874,159–35,093,509, 2 genes, copy number 7: AC087343.1, AC099685.1.
- chr8:35,862,123–38,973,912, 78 genes, copy number 7–11 (broad region; genes not listed).
- chr8:46,028,804–51,809,445, 80 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:86,866,415–88,887,573, 14 genes, copy number 7 (within-gene range 6–7): CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3.
- chr8:90,621,995–130,443,674, 589 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:133,036,728–141,507,230, 96 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr10:7,559,270–10,795,047, 35 genes, copy number 8 (within-gene range 4–8): ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P.
- chr10:10,917,866–10,952,234, 1 gene, copy number 8 (within-gene range 6–8): LINC00710.
- chr11:55,262,155–58,796,854, 208 genes, copy number 7–8 (broad region; genes not listed).
- chr11:104,682,383–105,531,697, 17 genes, copy number 7 (within-gene range 5–7): AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP.
- chr16:60,925,733–62,808,706, 12 genes, copy number 9–14: AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1.
- chr16:63,066,526–63,066,990, 1 gene, copy number 14: AC040174.2.
- chr17:20,185,082–20,844,257, 47 genes, copy number 7 (within-gene range 4–7): AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6.
- chr17:20,855,946–20,857,317, 1 gene, copy number 7: AC090774.2.
- chr19:27,681,072–30,228,715, 61 genes, copy number 9–11 (broad region; genes not listed).
- chr19:52,130,548–54,670,359, 221 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr19:55,039,108–56,379,828, 97 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:20,970,448–22,886,068, 41 genes, copy number 7–10: AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4.
- chr20:30,278,906–33,656,423, 104 genes, copy number 8 (broad region; genes not listed).
- chr21:20,998,409–25,057,746, 39 genes, copy number 8–11 (within-gene range 3–11): NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1.

Autosomal genes at a single copy (total copy number 1): 1,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
